TCGA case TCGA-A7-A26E — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/011b9b2d-ebe5-42bf-9662-d922faccc7a1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Alive.

Diagnoses (3)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 71.9 years (26,274 days); Year of diagnosis: 2010; Method of diagnosis: Core Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 16; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 101 days; Days to treatment end: 164 days; Number of cycles: 4; Treatment dose: 4,000 mg; Prescribed dose: 1000; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 101 days; Days to treatment end: 164 days; Number of cycles: 4; Treatment dose: 520 mg; Prescribed dose: 130; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 205 days; Days to treatment end: 246 days; Treatment dose: 9,720 cGy; Course number: 1; Number of fractions: 54; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Days to treatment start: 247 days; Number of cycles: 174; Treatment outcome: Treatment Ongoing; Prescribed dose: 1; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Laterality: Right; Classification of tumor: Synchronous primary; AJCC staging edition: 7th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 421 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 954 days (2.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ESR1 (IHC): Positive; Staining intensity scale: 3 Point Scale; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity scale: 3 Point Scale; Test value range: 20-29%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A7-A26E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-A7-A26E-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A7-A26E-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide TCGA-A7-A26E-01B-03-BS3: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A26E-01B-04-BS4: Section location: Bottom; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A26E-01B-06-BS6: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
  Slide TCGA-A7-A26E-01B-05-BS5: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-A7-A26E-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A7-A26E-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Prospective collection: Yes; Retrospective collection: No; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Arimidex.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Taxotere.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -2610.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Lobular carcinoma in situ, ductal carcinoma in situ, and invasive ductal carcinoma.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: 43.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 954 days; disease-specific survival: no event (censored), 954 days; disease-free interval: no event (censored), 954 days; progression-free interval: no event (censored), 954 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A7-A26E-01A-11D-A275-01): tumor purity 0.72, ploidy 1.96, whole-genome doublings 0.
